Gene-level copy-number profile of tumor specimen TCGA-13-0800-01A from TCGA case TCGA-13-0800, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 52.3 years (19,087 days).
Specimen TCGA-13-0800-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.c1508580-23b1-433b-adbb-70473a7105e6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-0800-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ab331117-622c-437a-8b23-7c745791e34e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 14; copy number 2: 7,507; copy number 3: 29,621; copy number 4: 9,213; copy number 5: 8,439; copy number 6: 432; copy number 7: 2,672; copy number 8: 1,040; copy number 10: 206; copy number 11: 65; copy number 13: 514; copy number 15: 64; copy number 16: 10; copy number 24: 11; copy number 25: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-13-0800-01A-01D-0356-01): tumor purity 0.8, ploidy 3.59, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 4,589 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:290,941–98,731,132, 1,787 genes, copy number 7–8 (within-gene range 5–8) (broad region; genes not listed).
- chr4:49,096–13,484,365, 328 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr6:24,667,035–107,133,170, 1,649 genes, copy number 7–24 (within-gene range 6–24) (broad region; genes not listed).
- chr6:107,192,300–107,230,152, 2 genes, copy number 24: AL591516.1, RPS24P12.
- chr6:109,690,609–110,358,272, 7 genes, copy number 25: FIG4, GPR6, AL590009.1, WASF1, CDC40, METTL24, AL050350.1.
- chr19:5,691,834–6,205,121, 26 genes, copy number 11 (within-gene range 2–11): LONP1, CATSPERD, PRR22, AC011499.1, DUS3L, NRTN, FUT6, FUT3, AC024592.2, FUT5, AC024592.3, NDUFA11, AC024592.1, AC104532.1, VMAC, AC104532.2, CAPS, RANBP3, AC011444.1, RFX2, AC011444.2, AC011444.4, AC011444.3, ACSBG2, AC011471.1, AC011471.4.
- chr19:8,520,778–12,758,458, 253 genes, copy number 13 (broad region; genes not listed).
- chr19:12,995,475–18,333,573, 280 genes, copy number 13–15 (broad region; genes not listed).
- chr19:29,489,775–29,617,237, 4 genes, copy number 11: AC011474.2, AC011474.4, VSTM2B, POP4.
- chr19:35,042,902–35,347,361, 22 genes, copy number 10 (within-gene range 2–10): HPN-AS1, AC020907.1, AC020907.6, FXYD3, MIR6887, LGI4, AC020907.5, FXYD1, AC020907.2, FXYD7, FXYD5, FAM187B, FAM187B2P, LSR, AC002128.2, AC002128.1, USF2, HAMP, MAG, CD22, U62631.1, MIR5196.
- chr19:37,312,837–37,369,365, 1 gene, copy number 10 (within-gene range 2–10): ZNF875.
- chr19:37,337,236–40,426,702, 159 genes, copy number 10 (broad region; genes not listed).
- chr19:44,228,729–44,305,046, 1 gene, copy number 11 (within-gene range 3–11): ZNF235.
- chr19:44,259,880–44,931,386, 36 genes, copy number 10–11: ZNF233, AC138473.1, NDUFA3P1, ZNF112, AC245748.1, ZNF285, AC245748.2, ZNF229, ZNF285B, ZNF180, CEACAM20, AC245748.3, CEACAM22P, AC243964.1, IGSF23, AC243964.3, PVR, MIR4531, CEACAM19, AC243964.4, CEACAM16, AC243964.2, BCL3, MIR8085, SNORA70, AC092066.1, CBLC, AC092306.1, BCAM, NECTIN2, AC011481.2, TOMM40, APOE, AC011481.3, APOC1, APOC1P1.
- chr19:53,599,628–53,658,462, 6 genes, copy number 11: AC011487.2, OSTCP3, RN7SL317P, DPRX, RNU6-698P, AC011453.2.
- chr19:53,745,004–53,943,941, 28 genes, copy number 15 (within-gene range 3–15): RNU6-982P, MIR521-1, RNU6-751P, MIR522, MIR519A1, MIR527, MIR516A1, MIR1283-2, RNU6-1041P, MIR516A2, AC011453.1, MIR519A2, RNU6-165P, HMGN1P32, SEPTIN7P8, AC008753.1, AC008753.3, MIR371A, MIR371B, MIR372, MIR373, AC008753.2, NLRP12, MYADM-AS1, MYADM, AC008440.1, PRKCG, CACNG7.

Autosomal genes at a single copy (total copy number 1): 14. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
